TCGA case TCGA-DX-A23V — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/212c9acc-d5ad-4b31-91bc-7ab72233aec6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 57 years; Vital status: Dead; Days to death: 2,034 days (5.6 years).

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 57.9 years (21,155 days); Year of diagnosis: 2003; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.6; Tumor length measurement: 1; Tumor width measurement: 1.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 13.
   Pathology details: Consistent pathology review: Yes; Tumor depth descriptor: Deep.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma). Age at diagnosis: 59.0 years (21,533 days); Days to diagnosis: 378 days (1.0 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 378 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 378 days (1.0 years).
- Days to follow up: 2,034 days (5.6 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A23V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-DX-A23V-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A23V-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A23V-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Disease multifocal indicator: Yes.
- Primary pathology, Tumor sizes, Tumor size 2: Lesion pathologic length: 1; Lesion pathologic width: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,034 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,034 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 378 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A23V-01A-11D-A29M-01): tumor purity 0.44, ploidy 2.03, whole-genome doublings 0.
